Somatic mutation profile of tumor specimen C3L-00589-01 (aliquot CPT0063970007_1) from CPTAC case C3L-00589, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.3 years (29,322 days).
Specimen C3L-00589-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 234a1b7e-9a2c-442c-8dff-56c1560df46b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00589-31 (Blood Derived Normal), aliquot CPT0065360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaac71ea-8c86-492e-8639-7e07863ec5f9

The open-access MAF lists 110 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 23, Nonsense Mutation 4, RNA 3, Splice Region 2, Frame Shift Ins 2, Intron 2, 5'Flank 2, Frame Shift Del 2, In Frame Del 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 70/324 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MTO1 | c.1399C>T p.R467* (on ENST00000370300 / NM_133645.3; = p.R442* on NM_012123.4) | Nonsense Mutation (SNP) | VAF 38/612 reads (6%) | catalogued as rs200583827, COSV64773263; ClinVar: likely pathogenic; called by muse, mutect2
- PDYN | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 42/543 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201486601, CM107860, COSV54101259; ClinVar: pathogenic; called by muse, mutect2
- TNR | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 16/226 reads (7%) | catalogued as rs1287757170, COSV99687070; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 124/594 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS10 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 90/984 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV54357422; called by muse, mutect2
- ADCY8 | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs374456387; called by muse, mutect2
- AFF2 | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60681163; called by muse, mutect2, varscan2
- ANKK1 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs775477797; called by muse, mutect2
- ASTN1 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 36/653 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770266633, COSV56089388; called by muse, mutect2
- CAPN8 | c.1765-8G>A | Splice Region (SNP) | VAF 22/326 reads (7%) | catalogued as rs566314619; called by muse, mutect2
- CCDC154 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 113/1512 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs113602113; called by muse, mutect2
- CCDC91 | c.654+1G>A p.X218_splice | Splice Site (SNP) | VAF 9/120 reads (8%) | catalogued as rs1311523701; called by muse, mutect2
- CHPF | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 40/445 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs1336922788, COSV60535208; called by muse, mutect2
- CLEC18A | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 8/736 reads (1%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs764034494; called by muse, mutect2
- COL1A1 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 64/788 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758897245, COSV56802381; called by muse, mutect2
- COL6A1 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 126/1294 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs373731596; called by muse, mutect2
- CTNNA2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs377364195; called by muse, mutect2
- GHRHR | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 70/799 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as rs200472991, COSV58197595; ClinVar: uncertain significance; called by muse, mutect2
- GPRC5B | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 88/1095 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148789431; called by muse, mutect2
- GRIK4 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs373630796; called by muse, mutect2, varscan2
- GSDMA | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 102/1794 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs754816059, COSV56977327; called by muse, mutect2
- HEY2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1316943640; called by muse, mutect2
- HTR3A | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 46/734 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369114231; called by muse, mutect2
- KCTD11 | c.602G>A p.R201H (on ENST00000333751 / NM_001363642.1; = p.R162H on NM_001002914.2) | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs865964999, COSV50134200; called by muse, mutect2
- LDLRAD3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100214374; called by muse, mutect2
- MACROD2 | c.353del p.R118Lfs*3 | Frame Shift Del (DEL) | VAF 30/334 reads (9%) | catalogued as COSV54026962; called by mutect2, pindel
- MEX3D | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 86/562 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV101183472; called by muse, mutect2, varscan2
- NFATC2 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs376937921; called by muse, mutect2
- NGEF | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs765885436, COSV50916867; called by muse, mutect2
- NINL | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs917252420; called by muse, mutect2, varscan2
- NOS1AP | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 52/842 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV62633557; called by muse, mutect2
- NPTX2 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 44/557 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375252857; called by muse, mutect2
- NRXN3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs779834039; called by muse, mutect2
- OR1M1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316702528; called by muse, mutect2
- PKD1 | c.3602C>T p.A1201V | Missense Mutation (SNP) | VAF 164/2165 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs773471530, CM143939; called by muse, mutect2
- PPP1R10 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1405225650; called by muse, mutect2
- PRKX | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs751998171; called by muse, mutect2, varscan2
- PTPRF | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs746910917, COSV63447231; called by muse, mutect2
- RASGEF1A | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 60/821 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767084570, COSV65666676; called by muse, mutect2
- ROBO1 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 44/410 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs778578401, COSV71394145; called by muse, mutect2, varscan2
- RP1 | c.2153A>G p.D718G | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1465609803; called by muse, mutect2, varscan2
- SETBP1 | c.1799C>T p.T600M | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201997891, COSV56322690; called by muse, mutect2
- SLC22A12 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 100/1068 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141975942; called by muse, mutect2
- SORCS2 | c.2968C>T p.R990W | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as rs375771681; called by muse, mutect2
- TRIM72 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 123/603 reads (20%) | catalogued as rs1356384611; called by muse, mutect2, varscan2
- UNC79 | c.4183C>T p.R1395W (on ENST00000393151 / NM_001346218.2; = p.R1218W on NM_020818.5) | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769549721, COSV56378995; called by muse, mutect2, varscan2
- ZBTB17 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 77/1123 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs757761976, COSV100998986; called by muse, mutect2
- AXIN2 | c.777_778insGG p.S260Gfs*3 | Frame Shift Ins (INS) | VAF 54/400 reads (14%) | called by mutect2, pindel, varscan2
- BRF1 | c.1340T>A p.L447Q | Missense Mutation (SNP) | VAF 39/562 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- BRWD3 | c.3808G>T p.D1270Y | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CALM1 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CSMD1 | c.10387T>C p.F3463L (on ENST00000520002; = p.F3462L on NM_033225.6) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- FAT4 | c.13769A>C p.N4590T | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- G6PD | c.1248_1249del p.E417Vfs*18 | Frame Shift Del (DEL) | VAF 132/809 reads (16%) | called by mutect2, pindel, varscan2
- GAS7 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 108/1189 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- GHRH | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 41/368 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- KCNS1 | c.370C>T p.H124Y | Missense Mutation (SNP) | VAF 46/447 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- KCNV1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 149/1298 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KLHL29 | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KMT2C | c.10772A>G p.Q3591R | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- LRRC9 | c.4037C>G p.P1346R | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- MN1 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- OR10G9 | c.595T>C p.F199L | Missense Mutation (SNP) | VAF 77/431 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAGR1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 34/633 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PIK3R6 | c.241A>T p.M81L | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PNLIPRP2 | c.1123A>G p.R375G (on ENST00000611850; = p.R376G on NM_005396.5) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRO | c.596C>G p.T199S | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2
- RAB11FIP4 | c.1413G>T p.E471D | Missense Mutation (SNP) | VAF 44/543 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SLC34A2 | c.1522_1527del p.T508_R509del | In Frame Del (DEL) | VAF 94/900 reads (10%) | called by mutect2, pindel
- STARD9 | c.8195T>A p.V2732D | Missense Mutation (SNP) | VAF 69/381 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNS4 | c.2132A>T p.D711V | Missense Mutation (SNP) | VAF 28/339 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- TRAF3IP3 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 89/301 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.75057dup p.Y25020Ifs*4 (on ENST00000591111; = p.Y17596Ifs*4 on NM_003319.4) | Frame Shift Ins (INS) | VAF 24/226 reads (11%) | called by mutect2, pindel, varscan2
- WDR47 | c.1727G>T p.G576V (on ENST00000369962 / NM_001142551.2; = p.G577V on NM_014969.5) | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2
- ZFPM1 | c.1041C>T p.S347= | Splice Region (SNP) | VAF 48/560 reads (9%) | called by muse, mutect2
- ZNF551 | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2
- ACTN2 | c.1392C>T p.I464= | Silent (SNP) | VAF 48/775 reads (6%) | catalogued as rs764086805, COSV63971447, COSV63972072; ClinVar: likely benign; called by muse, mutect2
- ADAMTS13 | c.1911G>T p.L637= | Silent (SNP) | VAF 49/502 reads (10%) | called by muse, mutect2
- BICDL2 | c.354C>T p.A118= | Silent (SNP) | VAF 60/848 reads (7%) | catalogued as rs1433439192; called by muse, mutect2
- C5AR2 | c.9C>T p.N3= | Silent (SNP) | VAF 42/652 reads (6%) | catalogued as rs1430628557, COSV57256903; called by muse, mutect2
- CDC20B | c.1095G>A p.P365= | Silent (SNP) | VAF 74/729 reads (10%) | catalogued as rs375917242; called by muse, mutect2, varscan2
- CXorf58 | c.606C>T p.N202= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs372466657, COSV64858132; called by muse, mutect2, varscan2
- DMRT3 | c.264C>T p.P88= | Silent (SNP) | VAF 41/271 reads (15%) | called by muse, mutect2, varscan2
- ECEL1 | c.1212C>T p.R404= | Silent (SNP) | VAF 64/479 reads (13%) | catalogued as rs764036925, COSV58812069; called by muse, mutect2, varscan2
- FAM187B | c.369G>A p.L123= | Silent (SNP) | VAF 74/719 reads (10%) | catalogued as rs1375864874; called by muse, mutect2, varscan2
- MAP4K4 | c.1131G>A p.Q377= | Silent (SNP) | VAF 65/395 reads (16%) | called by muse, mutect2, varscan2
- MYH2 | c.1992G>A p.L664= | Silent (SNP) | VAF 32/421 reads (8%) | called by muse, mutect2
- MYO16 | c.4152G>A p.A1384= | Silent (SNP) | VAF 52/586 reads (9%) | called by muse, mutect2
- NAALADL1 | c.1152C>T p.A384= | Silent (SNP) | VAF 36/382 reads (9%) | catalogued as rs368997186; called by muse, mutect2
- NCAM1 | c.1803C>T p.S601= (on ENST00000316851 / NM_181351.5; = p.S591= on NM_000615.7) | Silent (SNP) | VAF 40/514 reads (8%) | catalogued as rs536431053, COSV57516384; called by muse, mutect2
- OBSL1 | c.3915C>T p.D1305= | Silent (SNP) | VAF 36/371 reads (10%) | catalogued as rs926056344; called by muse, mutect2, varscan2
- PTPN3 | c.1848C>T p.P616= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs756050290, COSV99355862; called by muse, mutect2, varscan2
- RFX1 | c.879C>T p.S293= | Silent (SNP) | VAF 32/431 reads (7%) | catalogued as rs951951549, COSV54334046; called by muse, mutect2
- RGL2 | c.78G>C p.R26= | Silent (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- RIMBP2 | c.2115C>T p.D705= | Silent (SNP) | VAF 86/526 reads (16%) | catalogued as rs761677291, COSV55467808; called by muse, mutect2, varscan2
- TLL1 | c.2610T>G p.S870= | Silent (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- TTBK2 | c.1278C>T p.V426= | Silent (SNP) | VAF 52/622 reads (8%) | catalogued as rs1490347590; called by muse, mutect2
- UBAC1 | c.480C>T p.I160= | Silent (SNP) | VAF 26/399 reads (7%) | catalogued as rs1248931704; called by muse, mutect2
- ZNF335 | c.303C>T p.G101= | Silent (SNP) | VAF 10/191 reads (5%) | catalogued as rs868406297, COSV59817884, COSV59819402; called by muse, mutect2
- ADAM19 | chr5:157480971 C>A | 3'Flank (SNP) | VAF 15/391 reads (4%) | called by muse, mutect2
- CCDC187 | c.*2698C>T | 3'UTR (SNP) | VAF 20/259 reads (8%) | catalogued as rs1055911551; called by muse, mutect2
- FAM183BP | n.612C>T | RNA (SNP) | VAF 21/306 reads (7%) | called by muse, mutect2
- GLRXP3 | n.85G>A | RNA (SNP) | VAF 67/391 reads (17%) | called by muse, mutect2, varscan2
- NRG1 | chr8:31639417 G>A | 5'Flank (SNP) | VAF 75/855 reads (9%) | catalogued as rs777329120; called by muse, mutect2
- PPP1R9A | c.2757+552A>T | Intron (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- PSPN | chr19:6375850 T>A | 5'Flank (SNP) | VAF 72/1005 reads (7%) | called by muse, mutect2
- PTPRS | c.-25C>T | 5'UTR (SNP) | VAF 38/499 reads (8%) | catalogued as rs1295173495; called by muse, mutect2
- SLC25A51P4 | n.827G>A | RNA (SNP) | VAF 29/297 reads (10%) | catalogued as rs761032308; called by muse, mutect2
- UBXN2B | c.533+356T>C | Intron (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
